Surgical pathology report (de-identified scan), TCGA case TCGA-DU-7014, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-7014-01A (Primary Tumor).

[page 1 of 2]
PATHOLOGICAL DIAGNOSIS:

- A. BRAIN, RIGHT FRONTO-TEMPORAL, EXCISIONAL BIOPSY: GLIOMA WITH MICROCYSTIC CHANGE, LOW HISTOLOGICAL GRADE. MIB-1 PROLIFERATION INDEX: 1%.
- B. BRAIN, RIGHT FIRM TUMOR, EXCISION: OLIGODENDROGLIOMA, WITH ATYPICAL FEATURES. MIB-1 PROLIFERATION INDEX: 2%.

SEE MICROSCOPIC AND COMMENT.

Operation/Specimen: Brain.

Clinical History and Pre-Op Dx: Man with very large right frontal tumor, non-enhancing, with central cystic area.

GROSS PATHOLOGY:

- A. Received fresh, one fragment, 0.8 cm across. Soft, grayish-white and glistening. In total #1.

INTRAOPERATIVE CONSULTATION:

1. Brain, imprint: Cellular, glial nuclei.
2. Brain, squash preparations: Glioma, nuclear pleomorphism, no other features of anaplasia.

MICROSCOPIC: A. Portions of a diffusely infiltrating glial neoplasm with prominent microcystic change. The neoplastic cells have a round outline with some degree of pleomorphism. Mitotic figures, microvascular cellular proliferation, and necrosis are absent.

B. Portions of brain diffusely infiltrated by a neoplastic proliferation of glial cells. The neoplastic cells are primarily round naked nuclei disposed in a fine fibrillary background. Reactive astrocytes are observed in between the neoplastic cells. Focal hypercellular zones, and zones with neovascularization but without appreciable microvascular cellular proliferation, are present. There is moderate nuclear pleomorphism.

SPECIAL STAINS: Immunoperoxidase stains for GFAP, and MIB-1 are performed on sections from blocks #1 and 4. The GFAP demonstrates a scant finely fibrillary background. With the MIB-1 proliferation indices of 1% or 2% are determined in the more active areas.

[page 2 of 2]
COMMENT: The neoplasm is a diffusely infiltrating glioma with focal areas of microcystic change. The cells diffusely infiltrate the brain, and the tumor is devoid of appreciable mitotic activity or necrosis. There is a fine fibrillary background and the MIB-1 proliferation index is 1% or 2%. These features are those of a low grade (WHO II/IV) oligodendroglioma. However, the neovascularization and the more cellular areas may portend a more aggressive behavior.

Source: NCI Genomic Data Commons file 20d8bc0d-9438-4079-b72e-4ca1bb7b675e (TCGA-DU-7014.A848A22C-C92D-42CC-8E0B-8E260B1F5622.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).